Somatic mutation profile of tumor specimen TARGET-30-PAPRXW-01A (aliquot TARGET-30-PAPRXW-01A-01D) from TARGET case TARGET-30-PAPRXW, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.4 years (888 days).
Specimen TARGET-30-PAPRXW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1b72e24-fe41-4627-96cd-ee49ccb8541f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPRXW-10A (Blood Derived Normal), aliquot TARGET-30-PAPRXW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bee052cb-ea92-4b73-8d20-6589680b45a8

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 59/131 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGBL5 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs752895921, COSV59937527; called by muse, mutect2, varscan2
- AHNAK | c.11839G>T p.G3947* | Nonsense Mutation (SNP) | VAF 145/477 reads (30%) | catalogued as COSV57224286; called by muse, mutect2, varscan2
- BCDIN3D | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as COSV61702721; called by muse, mutect2, varscan2
- BEST3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs759773937, COSV58303887; called by muse, mutect2, varscan2
- EIF5 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV53685013, COSV53685946, COSV53687255; called by muse, mutect2, varscan2
- FBXO39 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV58622668; called by muse, mutect2, varscan2
- PDGFRB | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139554380, COSV55807667; called by mutect2, varscan2
- PRSS35 | c.893C>A p.T298K | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV63800358, COSV63801021; called by muse, mutect2, varscan2
- REV3L | c.4667A>T p.Q1556L | Missense Mutation (SNP) | VAF 116/307 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.049); catalogued as COSV62621841; called by muse, mutect2, varscan2
- RGS13 | c.227G>C p.R76P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV67345566, COSV67346108, COSV67346441; called by muse, mutect2, varscan2
- RPL26 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53447383; called by muse, mutect2, varscan2
- PFAS | c.2931G>T p.E977D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- REM1 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- C8orf58 | c.840G>T p.V280= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV51516306; called by muse, mutect2, varscan2
- DPY19L1 | c.1704G>A p.R568= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs753688668, COSV60583505; called by muse, mutect2, varscan2
- OR1D2 | c.171C>G p.T57= | Silent (SNP) | VAF 93/214 reads (43%) | catalogued as rs779551333, COSV58922158; called by muse, mutect2, varscan2
- RYR3 | c.5142A>T p.V1714= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV66802992; called by muse, mutect2, varscan2
